MMRF case MMRF_2180 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9133bcce-48fc-48e7-bbea-90e9776a1bf6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.2 years (21,977 days); ISS stage: II; Days to last known disease status: 857 days (2.3 years); Days to last follow up: 857 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 102 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 102 days; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Carfilzomib + Lenalidomide + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 380 days (1.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 0): M Protein 1.03 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 28.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.725 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 5.2 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 7.15 mmol/L; C-Reactive Protein 0.53 mg/dL.
- Day 79 (ECOG 0): M Protein 0.72 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.905 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 4.28 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 7.32 mmol/L.
- Day 162 (ECOG 1): M Protein 0.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 41.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 16.8 mmol/L.
- Day 255 (ECOG 1): M Protein 0.66 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.513 mg/dL; Immunoglobulin G 9.83 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.82 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 11.3 mmol/L.
- Day 353 (ECOG 1): M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.225 mg/dL; Immunoglobulin G 9.11 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.95 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 10.6 mmol/L.
- Day 423: M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.125 mg/dL; Immunoglobulin G 9.29 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.92 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 14.1 mmol/L.
- Day 493 (ECOG 1): M Protein 0.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.708 mg/dL; Immunoglobulin G 9.36 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 7.32 mmol/L.
- Day 584 (ECOG 1): M Protein 0.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.487 mg/dL; Immunoglobulin G 8.83 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 3.07 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.92 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 6.82 mmol/L.
- Day 696 (ECOG 1): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.438 mg/dL; Immunoglobulin G 7.98 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 5.4 g/dL; Glucose 8.64 mmol/L.
- Day 757 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.554 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 3.98 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 9.41 mmol/L.
- Day 857: M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.55 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 6.27 mmol/L.

Other clinical attributes
- Day -20: Weight: 93 kg; Height: 154 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2180_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_2180_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
